Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A28Z, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A28Z-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Papillary thyroid cancer.

PROCEDURE: Total thyroidectomy.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered

ADDENDA:**Addendum**

Collection Date:

1CD-0-3

Carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

lw
5/25/11**MOLECULAR ANATOMIC PATHOLOGY TESTING:**

Block A (left lobe thyroid papillary carcinoma 1.0 cm):

A. *RET/PTC1* rearrangement IDENTIFIED.B. Mutations in *BRAF*, *NRAS61*, *HRAS61*, *KRAS12/13* and *RET/PTC3* rearrangements NOT identified.

Block B (left lobe thyroid papillary carcinoma 1.0 cm):

A. *RET/PTC1* rearrangement IDENTIFIED.B. Mutations in *BRAF*, *NRAS61*, *HRAS61*, *KRAS12/13* and *RET/PTC3* rearrangements NOT identified.

Block C (left lobe thyroid papillary carcinoma 1.0 cm):

A. *RET/PTC1* rearrangement IDENTIFIED.B. Mutations in *BRAF*, *NRAS61*, *HRAS61*, *KRAS12/13* and *RET/PTC3* rearrangements NOT identified.

NOTE: Nucleic acids were extracted in the amount sufficient for testing.

FINAL DIAGNOSIS:

PART 1: THYROID, TOTAL THYROIDECTOMY (20 GRAMS) -

- A. THREE FOCI OF PAPILLARY THYROID CARCINOMA IN LEFT LOBE (1.0 CM, 1.0 CM, AND 1.0 CM).
- B. EXTRATHYROIDAL EXTENSION IS PRESENT AND TUMOR FOCALLY EXTENDS TO WITHIN 1 MM OF RESECTION MARGIN.
- C. THREE RIGHT PERITHYROIDAL LYMPH NODES FREE OF TUMOR.
- D. PATHOLOGIC STAGE T3 N1a.
- E. CHRONIC LYMPHOCYTIC THYROIDITIS.

PART 2: CENTRAL COMPARTMENT CONTENTS, DISSECTION -

- A. METASTATIC PAPILLARY THYROID CARCINOMA IN ONE OF THIRTEEN LYMPH NODES.
- B. THE LYMPH NODE IS CONSIDERED POSITIVE BECAUSE OF THE PRESENCE OF PSAMMOMA BODY, HOWEVER, NO TUMOR CELLS ARE SEEN.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY THYROID TUMORS**

SPECIMEN TYPE: Total Thyroidectomy

TUMOR SITE:

Left Lobe

TUMOR FOCALITY:

Multifocal

TUMOR SIZE (largest nodule):

Greatest Dimension: 1 cm

HISTOLOGIC TYPE**:

Papillary carcinoma

PRIMARY TUMOR (pT):

pT3

REGIONAL LYMPH NODES (pN):

pN1a

Number of regional lymph nodes examined: 16

Number of regional lymph nodes involved: 1

DISTANT METASTASIS (pM):

Not applicable

MARGINS:

Margins uninvolved by carcinoma

LYMPH-VASCULAR INVASION:

Not identified

ADDITIONAL PATHOLOGIC FINDINGS:

Other: Chronic lymphocytic thyroiditis

Source: NCI Genomic Data Commons file c1074945-1914-47f3-9a6d-e18cf37de341 (TCGA-BJ-A28Z.C0AFDCE6-F0D8-473C-A584-25DD53E2F832.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).